Somatic mutation profile of tumor specimen MMRF_2646_1_BM_CD138pos (aliquot MMRF_2646_1_BM_CD138pos_T1_KHS5U_L13418) from MMRF case MMRF_2646, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.8 years (20,760 days).
Specimen MMRF_2646_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 869dfe67-a766-4a25-b4d6-a244afe79bbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2646_2_PB_WBC (Blood Derived Normal), aliquot MMRF_2646_2_PB_WBC_C1_KHS5U_L13419; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5885cb09-9e73-4e65-b801-a8b48f7a8a08

The open-access MAF lists 92 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 18, Silent 12, Intron 10, 5'UTR 5, Splice Site 4, RNA 3, Nonsense Mutation 3, 5'Flank 1, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 281/526 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BCL7A | c.92+2T>C p.X31_splice | Splice Site (SNP) | VAF 30/118 reads (25%) | catalogued as rs200458522; called by muse, mutect2, varscan2
- HFM1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs762598590; called by muse, mutect2, varscan2
- IGHV2-70 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs377155486; called by muse, varscan2
- IGHV2-70 | c.147C>G p.S49R | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs376260160; called by muse, varscan2
- IGKC | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as rs570083381; called by muse, mutect2, varscan2
- IGLV3-1 | c.62A>T p.Y21F | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as rs145382269; called by muse, varscan2
- IGLV3-1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs143830449; called by muse, varscan2
- IGSF10 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148699040, COSV56783487; called by muse, mutect2, varscan2
- IK | c.481C>A p.H161N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101341820; called by muse, mutect2, varscan2
- LRRIQ1 | c.3502C>A p.Q1168K | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV67836056; called by muse, mutect2, varscan2
- LTB | c.163-8C>T | Splice Region (SNP) | VAF 153/540 reads (28%) | catalogued as rs767488608, COSV53001079; called by muse, mutect2, varscan2
- PEG3 | c.2614C>T p.R872* | Nonsense Mutation (SNP) | VAF 98/218 reads (45%) | catalogued as COSV55651101; called by muse, mutect2, varscan2
- PTX4 | c.538C>G p.P180A (on ENST00000447419 / NM_001328608.2; = p.P175A on NM_001013658.1) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.057); catalogued as rs1427031329; called by muse, mutect2, varscan2
- SCML2 | c.1355T>A p.F452Y | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs778592411; called by muse, mutect2, varscan2
- SCML2 | c.1354T>A p.F452I | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52623734; called by muse, mutect2, varscan2
- SPATA20 | c.1125+1G>A p.X375_splice (on ENST00000356488 / NM_001258372.1; = p.X391_splice on NM_022827.4) | Splice Site (SNP) | VAF 48/153 reads (31%) | catalogued as rs757174327; called by muse, mutect2, varscan2
- ABCC9 | c.1048A>G p.N350D | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- AGBL1 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 59/261 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CDH5 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAOA | c.134-1G>A p.X45_splice | Splice Site (SNP) | VAF 113/345 reads (33%) | called by muse, mutect2, varscan2
- DDX41 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 155/288 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DPPA2 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2
- HSD17B7 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- IGHG1 | c.315_316del p.K105Nfs*11 | Frame Shift Del (DEL) | VAF 56/149 reads (38%) | called by mutect2, pindel, varscan2
- ITGA9 | c.665A>T p.K222I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KCNRG | c.203A>G p.H68R | Missense Mutation (SNP) | VAF 155/482 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL21 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LILRA1 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- MYO10 | c.673G>T p.V225F | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- MYO1C | c.320T>G p.V107G (on ENST00000648651 / NM_001080779.2; = p.V72G on NM_033375.5) | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- NAALADL2 | c.409A>C p.I137L | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NUP160 | c.3767G>A p.G1256E | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- OR2Z1 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PKHD1L1 | c.7030dup p.M2344Nfs*9 | Frame Shift Ins (INS) | VAF 33/99 reads (33%) | called by mutect2, pindel, varscan2
- RASA2 | c.2016+1G>A p.X672_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- REX1BD | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- RTKN2 | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 60/217 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, varscan2
- SENP1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- TMEM176A | c.354G>T p.R118S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TPMT | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- ZNF138 | c.948T>G p.F316L (on ENST00000307355 / NM_001367572.1; = p.F290L on NM_006524.4) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF300 | c.1328A>G p.E443G | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM33 | c.834G>A p.T278= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as rs1354748436; called by muse, mutect2, varscan2
- CAMTA2 | c.1110T>A p.P370= | Silent (SNP) | VAF 86/270 reads (32%) | called by muse, mutect2, varscan2
- DOCK1 | c.4356T>C p.N1452= | Silent (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- HOXB9 | c.657C>T p.A219= | Silent (SNP) | VAF 94/275 reads (34%) | catalogued as rs762920779; called by muse, mutect2, varscan2
- MUC16 | c.33600C>T p.V11200= | Silent (SNP) | VAF 37/170 reads (22%) | catalogued as rs779237266; called by muse, mutect2, varscan2
- NELL1 | c.1407G>A p.V469= | Silent (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- PCDHA2 | c.2157T>C p.T719= | Silent (SNP) | VAF 23/183 reads (13%) | called by muse, mutect2, varscan2
- PLPPR2 | c.243G>A p.G81= | Silent (SNP) | VAF 83/369 reads (22%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.1026C>T p.V342= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- SLC25A45 | c.234C>T p.S78= | Silent (SNP) | VAF 103/291 reads (35%) | called by muse, mutect2, varscan2
- SLIT2 | c.87G>A p.P29= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- WDR33 | c.2994T>G p.G998= | Silent (SNP) | VAF 87/268 reads (32%) | called by muse, mutect2, varscan2
- ARGLU1 | c.*891T>G | 3'UTR (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- BCL2L1 | c.*474T>C | 3'UTR (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- CDON | c.*1850A>G | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CLK4 | c.1215-21A>G | Intron (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- CPT1C | c.281+30C>T | Intron (SNP) | VAF 51/284 reads (18%) | called by muse, mutect2, varscan2
- CPT2 | c.-110C>A | 5'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- CXXC1 | c.1672-15C>A | Intron (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- DNAJC5 | c.*2802C>A | 3'UTR (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- FAM13B | c.*1921T>A | 3'UTR (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- FAT3 | c.*5201del | 3'UTR (DEL) | VAF 16/32 reads (50%) | catalogued as rs1296971567; called by mutect2, varscan2
- GRIA1 | chr5:153489798 C>T | 5'Flank (SNP) | VAF 48/93 reads (52%) | catalogued as rs1229026259; called by muse, mutect2, varscan2
- GVINP1 | n.3119C>T | RNA (SNP) | VAF 74/274 reads (27%) | called by muse, mutect2, varscan2
- HPD | c.241+66C>T | Intron (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- IGHV1-46 | c.-79A>G | 5'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, varscan2
- IGHV1-46 | c.-80G>A | 5'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, varscan2
- LENG8 | c.*1964G>T | 3'UTR (SNP) | VAF 51/203 reads (25%) | called by muse, mutect2, varscan2
- LINC02228 | n.197G>A | RNA (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- MAB21L1 | c.*505A>G | 3'UTR (SNP) | VAF 34/137 reads (25%) | called by muse, mutect2, varscan2
- MAN2B2 | c.2815-776C>A | Intron (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- MAP3K1 | c.*2269A>G | 3'UTR (SNP) | VAF 36/54 reads (67%) | called by muse, varscan2
- MCU | c.*1289T>C | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- NBPF7 | n.438G>A | RNA (SNP) | VAF 26/56 reads (46%) | catalogued as rs765258270; called by muse, mutect2, varscan2
- PI15 | c.*3616C>A | 3'UTR (SNP) | VAF 38/108 reads (35%) | called by muse, mutect2
- PIGQ | c.943-29G>T | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2
- POFUT2 | c.*1102_*1103insTCAGAG | 3'UTR (INS) | VAF 91/268 reads (34%) | called by mutect2, varscan2
- PRRG3 | c.*3270A>G | 3'UTR (SNP) | VAF 28/44 reads (64%) | catalogued as rs1158987721; called by muse, mutect2, varscan2
- RASGRP2 | c.-62C>T | 5'UTR (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- RUFY1 | c.311-159A>G | Intron (SNP) | VAF 30/71 reads (42%) | catalogued as rs1040719596; called by muse, mutect2, varscan2
- SCN1A | c.3430-44C>T | Intron (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- SUSD4 | c.*401T>A | 3'UTR (SNP) | VAF 45/135 reads (33%) | called by muse, mutect2, varscan2
- TMEM182 | c.*1492A>G | 3'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- TNFRSF19 | c.*1704dup | 3'UTR (INS) | VAF 17/81 reads (21%) | catalogued as rs544006252; called by mutect2, varscan2
- UBQLN1 | c.-130T>C | 5'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2
- UCHL5 | c.*404dup | 3'UTR (INS) | VAF 15/61 reads (25%) | catalogued as rs1307863033; called by mutect2, varscan2
- WDFY4 | c.5982+1318C>T | Intron (SNP) | VAF 42/165 reads (25%) | called by muse, mutect2, varscan2
- WDR97 | c.1700+16G>A | Intron (SNP) | VAF 56/168 reads (33%) | called by muse, mutect2, varscan2
- ZBTB40 | c.*3180G>A | 3'UTR (SNP) | VAF 30/64 reads (47%) | catalogued as rs778921366; called by muse, mutect2, varscan2
